Surgical pathology report (de-identified scan), TCGA case TCGA-14-0790, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-0790-01B (Primary Tumor).

[page 1 of 2]
AP Report

* Final Report *

TCGA-14-0790

Document Type: AP Report
Document Date: [REDACTED]
Document Status: Auth (Verified)
Document Title: AP REPORT
Encounter info: [REDACTED]

* Final Report *

AP REPORT

Patient: [REDACTED] Accession Number: [REDACTED]
Patient Number: [REDACTED]
Financial Number: [REDACTED]
Room/Bed: [REDACTED] PT: [REDACTED]
Admitting Physician: [REDACTED]
Ordering Physician: [REDACTED]

Date Collected: [REDACTED]
Date Received: [REDACTED]

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. LEFT FRONTAL BRAIN LESION, RESECTION, FS1A, TP1A:
- GLIOBLASTOMA (WHO GRADE IV).
2. LEFT FRONTAL BRAIN LESION, RESECTION:
- GLIOBLASTOMA (WHO GRADE IV).
- SEE COMMENT.

COMMENT:

This tumor is diffusely infiltrative and extensively involves the white and gray matter. It demonstrates regions of extreme hypercellularity as well as pseudopalisading necrosis and vascular proliferation.

SPECIMEN:

1. Left frontal brain lesion.
2. Left frontal brain lesion.

CLINICAL HISTORY/OPERATIVE FINDINGS:

Printed by: [REDACTED]
Printed on: [REDACTED]

Page 1 of 3
(Continued)

[page 2 of 2]
AP Report

* Final Report *

Left brain tumor.

GROSS DESCRIPTION:

Specimen #1 is received fresh for intraoperative consultation and specimen #2 is received in formalin. Both parts are received labeled with the patient's name and medical record number.

Part #1 is labeled as "left frontal brain lesion" and consists of multiple pieces of pink-tan tissue measuring 1.5 x 1.2 x 0.5 cm in aggregate. Representative tissue is submitted for frozen tissue diagnosis and a touch preparation. The remainder of the cryoblock is submitted in cassette "FS1A." The remainder of the tissue is submitted in cassette "1B."

Specimen #2 is labeled as "left frontal brain lesion" and consists of a portion of brain tissue, measuring 5.2 x 4.1 x 1.7 cm. The tissue surface is irregular with areas of necrosis and hemorrhage on cut surface. Representative tissue is submitted in cassettes "2A" through "2D."

INTRAOPERATIVE CONSULTATION:

FS1A, TP1A: LEFT FRONTAL BRAIN LESION, BIOPSY (FROZEN SECTION, TOUCH PREPARATION): HIGH GRADE GLIOMA.

MICROSCOPIC DESCRIPTION:

Microscopic examination performed.

Medical Records

Page 1 (End of Report)

Printed by:
Printed on:

Page 2 of 3
(Continued)

Source: NCI Genomic Data Commons file dd9d8ba6-aaaa-4088-a25f-0a51e968d7c0 (TCGA-14-0790.ED7342F3-4567-466C-A82A-AE6EF040A7C7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).